Somatic mutation profile of tumor specimen TCGA-49-4512-01A (aliquot TCGA-49-4512-01A-21D-1855-08) from TCGA case TCGA-49-4512, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 69.8 years (25,502 days).
Specimen TCGA-49-4512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0d1e5e7-26c5-4b5b-b4c5-7e47b41d4c42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4512-11A (Solid Tissue Normal), aliquot TCGA-49-4512-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a46e5a-09e0-48ae-85e4-8dcc09785753

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Splice Site 3, Frame Shift Del 2, Splice Region 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1190633013, COSV57433028; called by muse, mutect2, varscan2
- ANK2 | c.957G>T p.L319F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52170243; called by muse, mutect2, varscan2
- AP001453.3 | c.*473G>T | Splice Region (SNP) | VAF 34/189 reads (18%) | catalogued as COSV58588164; called by muse, mutect2, varscan2
- ARSD | c.1136-1G>C p.X379_splice | Splice Site (SNP) | VAF 20/85 reads (24%) | catalogued as COSV54202684; called by muse, mutect2, varscan2
- CDH10 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52584543, COSV52586176; called by muse, mutect2
- CDK5RAP2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs367746734; called by muse, mutect2, varscan2
- CEBPZ | c.1523T>C p.I508T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs752087907, COSV50018005; called by muse, mutect2, varscan2
- CNTNAP4 | c.1155C>A p.D385E | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV56687936; called by muse, mutect2
- COPS9 | c.115G>T p.V39F (on ENST00000607357 / NM_001163424.2; = p.V70F on NM_138336.1) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.419); catalogued as COSV56228451, COSV56229009, COSV56229090; called by muse, mutect2, varscan2
- DCAF12L2 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs374064147, COSV63580525; called by muse, mutect2
- DCDC1 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs781437821, COSV60836779, COSV60849362; called by muse, mutect2, varscan2
- EPS15L1 | c.309+1G>A p.X103_splice | Splice Site (SNP) | VAF 15/80 reads (19%) | catalogued as rs1342244494, COSV50170457; called by muse, mutect2, varscan2
- F9 | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD930965, CM940487, CM940488, CM993338, COSV54381114; called by muse, mutect2
- FLG | c.8773G>C p.D2925H | Missense Mutation (SNP) | VAF 54/1042 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100910564; called by muse, mutect2
- FRAS1 | c.8884G>T p.A2962S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53623022; called by muse, mutect2, varscan2
- MAP2K7 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276435407, COSV67608700; called by muse, mutect2, varscan2
- MED14 | c.1173+1G>T p.X391_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV61357455; called by muse, mutect2, varscan2
- NPY1R | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56715152; called by muse, mutect2, varscan2
- NRXN2 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as rs762261549, COSV55456673; called by muse, mutect2, varscan2
- NT5C1B | c.611G>A p.R204Q (on ENST00000359846 / NM_001199086.2; = p.R144Q on NM_033253.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.884); catalogued as COSV58395261; called by muse, mutect2, varscan2
- PTBP3 | c.41A>T p.K14M | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV52957873; called by muse, mutect2, varscan2
- RARS1 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as rs1296652512, COSV51564463; called by muse, mutect2
- RPS6KA3 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.83); catalogued as COSV65388390; called by muse, mutect2, varscan2
- SFMBT2 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779516999, COSV62811926; called by muse, mutect2
- TTN | c.22978C>G p.H7660D (on ENST00000591111; = p.H6733D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/316 reads (10%) | PolyPhen benign (0); catalogued as COSV60158002; called by muse, mutect2
- UBA3 | c.33_35del p.R13del | In Frame Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs1472051662; called by pindel, varscan2
- AR | c.2172T>A p.P724= | Splice Region (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- ASB17 | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLX3 | c.97_107del p.P33Cfs*3 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- DYNLL2 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- GLIPR1 | c.436dup p.S146Kfs*13 | Frame Shift Ins (INS) | VAF 12/109 reads (11%) | called by mutect2, pindel, varscan2
- KCNV2 | c.1267T>G p.F423V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- OR1E1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF318 | c.5782_5794del p.S1928Lfs*58 | Frame Shift Del (DEL) | VAF 33/169 reads (20%) | called by mutect2, pindel, varscan2
- AKAP9 | c.3684G>A p.E1228= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV62350266; called by muse, mutect2, varscan2
- CCT7 | c.255C>A p.S85= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV57822734; called by muse, mutect2
- DAGLA | c.2142G>A p.P714= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs1280029847, COSV57197465; called by muse, mutect2, varscan2
- GRIN2A | c.4089C>T p.S1363= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs774385825, COSV58029885, COSV58031261; called by muse, mutect2, varscan2
- LYST | c.4764C>T p.L1588= | Silent (SNP) | VAF 48/203 reads (24%) | catalogued as COSV67709030; called by muse, mutect2, varscan2
- OR5H1 | c.45A>G p.T15= | Silent (SNP) | VAF 20/255 reads (8%) | called by muse, mutect2
